Surgical pathology report (de-identified scan), TCGA case TCGA-BR-6565, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-6565-01A (Primary Tumor).

[page 1 of 2]
Formatted Path Report

STOMACH TISSUE CHECKLIST

Specimen type: Excision of tumor
Tumor site: Stomach
Tumor size: 7 x 6 x 1.5 cm
Tumor features: Ulcerated
Histologic type: Adenocarcinoma
Histologic grade: Moderately differentiated
Tumor extent: Serosa (visceral peritoneum)
Lymph nodes: 0/1 positive for metastasis (Regional 0/1)
Lymphatic invasion: Not specified
Venous invasion: Not specified
Perineural invasion: Not specified
Margins: Not specified
Evidence of neo-adjuvant treatment: Not specified
Additional pathologic findings: Not specified
Comments: None

[page 2 of 2]
Date of Procurement

--	--

Source: NCI Genomic Data Commons file 36fa00fe-2e81-4336-83a7-828dce2e039c (TCGA-BR-6565.94B9F261-6C6D-453A-9730-716F73FD73DF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).